Gene-level copy-number profile of tumor specimen TCGA-W5-AA2J-01A from TCGA case TCGA-W5-AA2J, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.1 years (24,140 days).
Specimen TCGA-W5-AA2J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6af8c545-8ade-43b4-b70b-3e9e169f8cb7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-W5-AA2J-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/041690ab-42ba-4650-8bca-a6afd2d0ee9b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 9,045; copy number 2: 42,597; copy number 3: 5,643; copy number 4: 938; copy number 5: 130; copy number 6: 10; copy number 43: 1; copy number 58: 1; copy number 61: 5; copy number 102: 2; copy number 117: 7; copy number 171: 3; copy number 213: 1; copy number 259: 3.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:57,081,745–57,264,679, 4 genes: AC034244.1, AC034244.2, Y_RNA, GPBP1.
- chr13:95,310,830–95,579,759, 5 genes (within-gene range 0–1): RNY3P8, RNY4P27, MEMO1P5, CLDN10, CLDN10-AS1.
- chr21:12,999,676–13,016,692, 1 gene: AP001464.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 163 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:1,905,651–1,906,125, 1 gene, copy number 5: RPL21P17.
- chr3:7,951,263–11,039,247, 80 genes, copy number 5–6 (broad region; genes not listed).
- chr3:12,287,368–12,434,356, 1 gene, copy number 5 (within-gene range 3–5): PPARG.
- chr3:12,484,432–14,574,792, 44 genes, copy number 5: TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17, CAND2, AC034198.2, RPL32, SNORA7A, AC034198.1, LINC02022, IQSEC1, AC069271.1, NUP210, AC027124.2, AC027124.1, HDAC11-AS1, HDAC11, FBLN2, LINC00620, WNT7A, VN1R20P, FGD5P1, TPRXL, AC090004.2, VN1R21P, CHCHD4, TMEM43, AC090004.1, XPC-AS1, XPC, LSM3, AC093496.1, LINC01267, RNA5SP124, SLC6A6, GRIP2, RNU6-905P, RHBDF1P1.
- chr3:15,601,341–16,264,969, 11 genes, copy number 5 (within-gene range 3–5): BTD, ANKRD28, MIR3134, AC090950.2, AC090950.1, RN7SL4P, AC090945.1, MIR563, IMPDH1P8, GALNT15, DPH3.
- chr3:19,148,510–19,702,795, 3 genes, copy number 5: KCNH8, MIR4791, AC061958.1.
- chr3:122,660,613–122,662,438, 1 gene, copy number 58: EIF4BP8.
- chr3:141,738,474–141,938,547, 7 genes, copy number 61–102 (within-gene range 2–102): AC112504.2, GRK7, HMGN2P25, ATP1B3, RNU6-509P, ATP1B3-AS1, AC112504.1.
- chr3:170,222,424–170,860,993, 15 genes, copy number 43–259: PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11, AC026316.4, MIR6828, SLC7A14-AS1, SLC7A14, KRT8P13, AC026316.1, AC026316.3, AC026316.5, AC026316.2.

Autosomal genes at a single copy (total copy number 1): 7,512. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
